CCDI case PBBILR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5e191226-50e1-4ed2-b9af-2c75fb459f5f

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.3 years (833 days).

Biospecimens (3 samples)
- Sample 0DC62Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DC632: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DC638: Tissue type: Tumor; Specimen type: Solid Tissue.
